Somatic mutation profile of tumor specimen ALCH-B0B0-TTP1-A (aliquot ALCH-B0B0-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B0B0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.2 years (25,629 days).
Specimen ALCH-B0B0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aee13469-6b0c-4f8c-b767-69e571c3db25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0B0-NB1-A (Blood Derived Normal), aliquot ALCH-B0B0-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ddc192a-2797-4779-8b14-5c26dc2ec862

The open-access MAF lists 1,053 somatic variants for this specimen: 723 protein-altering or splice-affecting, 217 silent, 113 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 590, Silent 217, Nonsense Mutation 57, Intron 42, RNA 34, Splice Site 26, Frame Shift Del 25, 3'UTR 14, Splice Region 13, Frame Shift Ins 10, 5'UTR 10, 5'Flank 8.

Variants (750 of 1,053; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 787/1043 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMCHD1 | c.1571A>G p.N524S | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs1135402745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG5 | c.28G>T p.G10* | Nonsense Mutation (SNP) | VAF 131/486 reads (27%) | catalogued as COSV53210574; called by muse, mutect2, varscan2
- ACSM4 | c.801del p.W267* | Frame Shift Del (DEL) | VAF 137/391 reads (35%) | catalogued as COSV68068786; called by mutect2, pindel, varscan2
- ADA2 | c.904G>T p.A302S (on ENST00000262607; = p.A61S on NM_177405.3) | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.009); catalogued as COSV52830715; called by muse, mutect2, varscan2
- ADAM18 | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 47/406 reads (12%) | catalogued as rs1359210878; called by muse, mutect2, varscan2
- ADAM19 | c.1679G>T p.G560V | Missense Mutation (SNP) | VAF 112/248 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57431067; called by muse, mutect2, varscan2
- ADAMTS4 | c.2144G>A p.R715Q | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs745913279; called by muse, mutect2
- ADAMTS6 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 91/337 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66856655; called by muse, mutect2, varscan2
- ADCY10 | c.3278C>A p.S1093Y | Missense Mutation (SNP) | VAF 133/409 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63244946; called by muse, mutect2, varscan2
- ADCY2 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 82/398 reads (21%) | catalogued as COSV57871006; called by muse, mutect2, varscan2
- AMDHD1 | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 159/354 reads (45%) | catalogued as COSV57140082; called by muse, mutect2, varscan2
- AMER3 | c.1556G>C p.R519P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.878); catalogued as COSV58470000; called by muse, mutect2
- ANTXR2 | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 208/888 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56321102; called by muse, mutect2, varscan2
- AP002512.3 | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99688202; called by muse, mutect2, varscan2
- APOB | c.10899G>T p.W3633C | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51938071; called by muse, mutect2, varscan2
- ARHGAP40 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 45/222 reads (20%) | catalogued as rs775661522; called by muse, mutect2, varscan2
- ARHGAP9 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 358/662 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1383744423; called by muse, mutect2, varscan2
- ARPP21 | c.918C>A p.S306R | Missense Mutation (SNP) | VAF 34/382 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs763439655; called by muse, mutect2
- BMX | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 154/349 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV59590516; called by muse, mutect2, varscan2
- C6 | c.706C>A p.L236M | Missense Mutation (SNP) | VAF 334/1358 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs755404217; called by muse, mutect2, varscan2
- CACNA1B | c.1399A>T p.K467* | Nonsense Mutation (SNP) | VAF 65/468 reads (14%) | catalogued as rs1554740641; called by muse, mutect2, varscan2
- CACNA1C | c.3571G>T p.E1191* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV59735171; called by muse, mutect2, varscan2
- CACNA1C | c.5021C>T p.T1674I | Missense Mutation (SNP) | VAF 91/295 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); catalogued as COSV59780620; called by muse, mutect2, varscan2
- CACNA1S | c.5153G>T p.C1718F | Missense Mutation (SNP) | VAF 39/313 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV100755083; called by muse, mutect2, varscan2
- CATSPERB | c.978G>T p.E326D | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV56432351; called by muse, mutect2, varscan2
- CBX2 | c.1076A>G p.Q359R | Missense Mutation (SNP) | VAF 119/381 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.532); catalogued as rs782370991; called by muse, mutect2, varscan2
- CD82 | c.700G>T p.V234L | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV57036874, COSV99907897; called by muse, mutect2, varscan2
- CDKL2 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 68/356 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56733569; called by muse, mutect2, varscan2
- CFAP47 | c.2167G>T p.G723* | Nonsense Mutation (SNP) | VAF 91/177 reads (51%) | catalogued as COSV52888593; called by muse, mutect2, varscan2
- CFH | c.1343G>T p.C448F | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM161599; called by muse, mutect2, varscan2
- CFH | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs372365885; called by muse, mutect2, varscan2
- CMTM5 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1432191575; called by muse, mutect2, varscan2
- COL11A1 | c.2893C>A p.P965T | Missense Mutation (SNP) | VAF 90/574 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62171610; called by muse, mutect2, varscan2
- COL11A1 | c.2809-1G>T p.X937_splice | Splice Site (SNP) | VAF 55/472 reads (12%) | catalogued as COSV100617945; called by muse, mutect2, varscan2
- COL11A1 | c.2731C>A p.P911T | Missense Mutation (SNP) | VAF 91/798 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62177557; called by muse, mutect2, varscan2
- COL13A1 | c.1910G>T p.G637V (on ENST00000398978 / NM_001130103.2; = p.G565V on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62567358; called by muse, mutect2, varscan2
- COL1A2 | c.2701G>T p.G901C | Missense Mutation (SNP) | VAF 99/837 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM973121, COSV51964300; called by muse, mutect2, varscan2
- COL3A1 | c.923G>T p.R308L | Missense Mutation (SNP) | VAF 244/1098 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV58581603; called by muse, mutect2, varscan2
- COL3A1 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 259/990 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1412593, COSV100482879; called by muse, mutect2, varscan2
- COL3A1 | c.4254+1G>T p.X1418_splice | Splice Site (SNP) | VAF 143/593 reads (24%) | catalogued as COSV58595738; called by muse, mutect2, varscan2
- COL6A5 | c.2792A>T p.H931L | Missense Mutation (SNP) | VAF 67/568 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.034); catalogued as COSV55201857; called by muse, varscan2
- COL6A5 | c.6167C>A p.A2056E (on ENST00000312481; = p.A2052E on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs1358352828; called by muse, mutect2, varscan2
- CORO7 | c.2755G>A p.V919M | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs543226131; called by muse, mutect2
- CPLX2 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1350139619; called by muse, mutect2, varscan2
- CRISP3 | c.535T>C p.Y179H (on ENST00000371159 / NM_001368123.1; = p.Y161H on NM_006061.4) | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.138); catalogued as rs755691145, COSV53819018; called by muse, mutect2, varscan2
- CSMD1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 30/313 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1048067890; called by muse, mutect2
- CSMD3 | c.2789G>T p.G930V (on ENST00000297405 / NM_001363185.1; = p.G826V on NM_052900.3) | Missense Mutation (SNP) | VAF 107/515 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52262560; called by muse, mutect2, varscan2
- CTNND2 | c.1371A>G p.T457= | Splice Region (SNP) | VAF 43/195 reads (22%) | catalogued as rs1298322060; called by muse, mutect2, varscan2
- CUBN | c.5075T>A p.L1692H | Missense Mutation (SNP) | VAF 181/738 reads (25%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.792); catalogued as rs779817240; called by muse, mutect2, varscan2
- CWC27 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 70/229 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101126540; called by muse, mutect2, varscan2
- CYLC2 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.099); catalogued as COSV99058680; called by muse, mutect2, varscan2
- DCHS2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.092); catalogued as rs867106022, COSV100251688; called by muse, mutect2, varscan2
- DDAH2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.223); catalogued as rs927682425; called by muse, mutect2
- DDI1 | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56376481; called by muse, mutect2, varscan2
- DKK2 | c.66G>T p.M22I | Missense Mutation (SNP) | VAF 145/713 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV53396700; called by muse, mutect2, varscan2
- DLGAP4 | c.427G>T p.V143F | Missense Mutation (SNP) | VAF 63/320 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59418306; called by muse, mutect2, varscan2
- DMXL1 | c.2763G>T p.K921N | Missense Mutation (SNP) | VAF 131/356 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs758215258; called by muse, mutect2, varscan2
- DMXL1 | c.4681C>T p.R1561* | Nonsense Mutation (SNP) | VAF 75/375 reads (20%) | catalogued as rs780539211, COSV60708338; called by muse, mutect2, varscan2
- DPYS | c.1460del p.P487Lfs*14 | Frame Shift Del (DEL) | VAF 80/667 reads (12%) | catalogued as COSV60914550; called by mutect2, pindel, varscan2
- EBF1 | c.749C>T p.S250L | Missense Mutation (SNP) | VAF 307/712 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as rs745519859, COSV58178713; called by muse, mutect2, varscan2
- EEF1AKNMT | c.930G>T p.E310D (on ENST00000361735 / NM_015935.5; = p.E224D on NM_014955.3) | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.279); catalogued as COSV100675855; called by muse, mutect2, varscan2
- EEF1G | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57745478; called by muse, mutect2, varscan2
- EFCAB5 | c.2640G>T p.K880N | Missense Mutation (SNP) | VAF 55/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs776969520; called by muse, mutect2, varscan2
- EPX | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.104); catalogued as COSV56598544; called by muse, mutect2, varscan2
- EYS | c.704G>T p.W235L | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as CM153010, COSV100675934; called by muse, mutect2, varscan2
- FAM170B | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs866574926, COSV61253270; called by muse, mutect2, varscan2
- FAM187A | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 100/317 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53653198; called by muse, mutect2, varscan2
- FAM47C | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 32/58 reads (55%) | catalogued as COSV63727370; called by muse, mutect2, varscan2
- FAP | c.1970-2A>T p.X657_splice | Splice Site (SNP) | VAF 42/187 reads (22%) | catalogued as rs759877611; called by muse, mutect2, varscan2
- FAT4 | c.12759G>T p.R4253S | Missense Mutation (SNP) | VAF 145/738 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58673710; called by muse, mutect2, varscan2
- FBXO39 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 142/395 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58621218; called by muse, mutect2, varscan2
- FCGBP | c.6820G>T p.G2274C | Missense Mutation (SNP) | VAF 163/784 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1315956102; called by muse, mutect2, varscan2
- FGA | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57394671; called by muse, mutect2, varscan2
- FGFR1 | c.1655C>A p.T552K (on ENST00000447712 / NM_023110.3; = p.T550K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/543 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58347371; called by muse, mutect2, varscan2
- FGG | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 173/702 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100272057; called by muse, mutect2, varscan2
- FLNC | c.4286C>A p.P1429Q | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57962457; called by muse, mutect2, varscan2
- FLRT2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58147425; called by muse, mutect2, varscan2
- FRY | c.5497G>T p.V1833F | Missense Mutation (SNP) | VAF 106/368 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV66569562; called by muse, mutect2, varscan2
- FSHR | c.369A>T p.Q123H | Missense Mutation (SNP) | VAF 90/380 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.13); catalogued as rs1351621076; called by muse, mutect2, varscan2
- GABRA6 | c.1254C>A p.D418E | Missense Mutation (SNP) | VAF 267/728 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs369062101; called by muse, mutect2, varscan2
- GABRG3 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100405554, COSV61519342; called by muse, mutect2, varscan2
- GABRQ | c.1089del p.R363Sfs*20 | Frame Shift Del (DEL) | VAF 206/394 reads (52%) | catalogued as rs782050509, COSV100941217, COSV64782025; called by mutect2, pindel, varscan2
- GABRR3 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as rs199624921; called by muse, mutect2
- GAP43 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV100525569; called by muse, mutect2, varscan2
- GBP4 | c.1029G>T p.Q343H | Missense Mutation (SNP) | VAF 133/498 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as COSV63252753; called by muse, mutect2, varscan2
- GOLGA6B | c.618G>T p.K206N | Missense Mutation (SNP) | VAF 192/2356 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1338550757, COSV69770199; called by muse, mutect2
- GPR171 | c.302C>T p.S101L | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56394513, COSV99854904; called by muse, mutect2, varscan2
- GREB1 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 103/459 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs532741308; called by muse, mutect2, varscan2
- GRIK5 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53482836; called by muse, mutect2, varscan2
- GRIP2 | c.394C>T p.R132C (on ENST00000619221; = p.R35C on NM_001080423.4) | Missense Mutation (SNP) | VAF 96/374 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs375887985, COSV56122802; called by muse, varscan2
- GRM8 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 96/384 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV100282286; called by muse, mutect2, varscan2
- HBB | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 242/796 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as CM900120; called by muse, mutect2, varscan2
- HGF | c.864C>A p.C288* | Nonsense Mutation (SNP) | VAF 159/668 reads (24%) | catalogued as rs374136304, CM088396; called by muse, mutect2, varscan2
- HLCS | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs1433394757, COSV60793088; called by muse, mutect2, varscan2
- HRNR | c.2881G>A p.G961S | Missense Mutation (SNP) | VAF 250/1735 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as rs1303172060, COSV100913817; called by muse, mutect2, varscan2
- HTR1B | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.142); catalogued as COSV100885363; called by muse, mutect2, varscan2
- HTRA3 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 18/209 reads (9%) | catalogued as COSV56469893; called by muse, mutect2
- IFI44L | c.953G>C p.C318S | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374146000, COSV60726626; called by muse, mutect2, varscan2
- IGDCC4 | c.1729A>G p.T577A | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs149303335; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.8G>T p.W3L | Missense Mutation (SNP) | VAF 68/607 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs757552862; called by muse, mutect2, varscan2
- IGKV1-12 | c.13G>T p.V5F | Missense Mutation (SNP) | VAF 269/1832 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.019); catalogued as rs1350631418; called by muse, mutect2, varscan2
- IGLJ3 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.398); catalogued as rs779967405; called by muse, mutect2
- IGSF9B | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 74/253 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as rs749882974, COSV58069041; called by muse, mutect2, varscan2
- IMPG1 | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as COSV64061051; called by muse, mutect2, varscan2
- ITGA8 | c.799C>A p.L267I | Missense Mutation (SNP) | VAF 75/288 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.556); catalogued as COSV65230610; called by muse, mutect2, varscan2
- ITGA8 | c.210-1G>T p.X70_splice | Splice Site (SNP) | VAF 37/234 reads (16%) | catalogued as COSV65230576; called by muse, mutect2, varscan2
- ITGB4 | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 130/544 reads (24%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.524); catalogued as COSV52332352; called by muse, varscan2
- ITPKB | c.599G>C p.R200P | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV55258641; called by muse, mutect2, varscan2
- JHY | c.680C>A p.P227Q | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56218965; called by muse, mutect2, varscan2
- JPH3 | c.1463C>A p.P488Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99414062; called by muse, mutect2
- KCNH3 | c.580G>T p.G194W | Missense Mutation (SNP) | VAF 66/125 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs199585532; called by muse, mutect2, varscan2
- KCNU1 | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs748129543, COSV101299439; called by muse, mutect2, varscan2
- KHDC4 | c.681G>T p.G227= | Splice Region (SNP) | VAF 418/783 reads (53%) | catalogued as COSV64165095; called by muse, mutect2, varscan2
- KHDC4 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 426/792 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV64165745; called by muse, mutect2, varscan2
- KLK2 | c.7del p.D3Tfs*65 | Frame Shift Del (DEL) | VAF 71/262 reads (27%) | catalogued as COSV99050925; called by mutect2, pindel, varscan2
- KRT4 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 93/812 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs201227331; called by muse, mutect2, varscan2
- LCE2B | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 128/908 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV64227722; called by muse, mutect2, varscan2
- LIN7A | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 141/380 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as COSV54017859; called by muse, mutect2, varscan2
- LINGO1 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV100796308; called by muse, mutect2, varscan2
- LMX1A | c.953C>A p.P318Q | Missense Mutation (SNP) | VAF 193/530 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV54217594, COSV99671818; called by muse, mutect2, varscan2
- LRRC7 | c.752G>T p.W251L (on ENST00000651989 / NM_001370785.2; = p.W218L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/423 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as COSV50554071; called by muse, mutect2, varscan2
- MATK | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 47/314 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.037); catalogued as rs774299917, COSV100036074; called by muse, mutect2, varscan2
- MBD5 | c.1164G>C p.Q388H | Missense Mutation (SNP) | VAF 234/1014 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68695892; called by muse, mutect2, varscan2
- MGAT5B | c.1732-1G>T p.X578_splice (on ENST00000569840 / NM_001199172.2; = p.X576_splice on NM_144677.3) | Splice Site (SNP) | VAF 39/186 reads (21%) | catalogued as COSV56935315; called by muse, mutect2, varscan2
- MMP19 | c.230G>T p.R77M | Missense Mutation (SNP) | VAF 189/398 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.405); catalogued as rs537015598; called by muse, mutect2, varscan2
- MTMR4 | c.4G>T p.G2C | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1194154445; called by muse, mutect2, varscan2
- MUC16 | c.6964G>T p.A2322S | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1243958593; called by muse, mutect2, varscan2
- MUC16 | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as COSV101201095; called by muse, mutect2, varscan2
- MUC5AC | c.16600G>C p.V5534L | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as rs781570443; called by muse, mutect2, varscan2
- MYH3 | c.3739G>T p.E1247* | Nonsense Mutation (SNP) | VAF 89/564 reads (16%) | catalogued as rs770539752; called by muse, mutect2, varscan2
- MYOM1 | c.3360G>T p.Q1120H | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as COSV55294772; called by muse, mutect2, varscan2
- NADK2 | c.559C>T p.R187W (on ENST00000381937 / NM_001085411.3; = p.R24W on NM_153013.4) | Missense Mutation (SNP) | VAF 49/340 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773035471, COSV56934989; called by muse, mutect2, varscan2
- NAP1L2 | c.1105T>A p.S369T | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1368584015; called by muse, mutect2, varscan2
- NID2 | c.1717C>A p.P573T | Missense Mutation (SNP) | VAF 111/440 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1342887997; called by muse, mutect2, varscan2
- NIN | c.6120G>C p.M2040I (on ENST00000382041 / NM_182946.1; = p.M1327I on NM_016350.4) | Missense Mutation (SNP) | VAF 55/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99811556; called by muse, mutect2, varscan2
- NKX2-4 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs778666048; called by muse, mutect2, varscan2
- NPC1L1 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 58/552 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as rs757842457; called by muse, varscan2
- NTM | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV66175580; called by muse, mutect2, varscan2
- NTRK1 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 54/724 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV62324754; called by muse, mutect2
- NUDCD1 | c.1249A>T p.S417C | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs1010152279; called by muse, mutect2, varscan2
- OCA2 | c.1870G>A p.A624T | Missense Mutation (SNP) | VAF 205/660 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs373739951; called by muse, mutect2, varscan2
- OR11L1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 126/338 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV63313810, COSV63315822; called by muse, mutect2, varscan2
- OR14A2 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867436643, COSV100825490; called by muse, mutect2, varscan2
- OR1J4 | c.916A>C p.N306H | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.003); catalogued as rs1564186319; called by muse, mutect2, varscan2
- OR2AJ1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); catalogued as rs1368156458, COSV59089281; called by muse, mutect2, varscan2
- OR2AK2 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV63550806; called by muse, mutect2, varscan2
- OR2M3 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 102/317 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV71758819; called by muse, mutect2, varscan2
- OR4A5 | c.584C>A p.T195N | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.694); catalogued as rs1216352785, COSV60523745, COSV60524235; called by muse, mutect2, varscan2
- OR4C6 | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 74/449 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV104404769; called by muse, mutect2, varscan2
- OR51D1 | c.708G>T p.W236C | Missense Mutation (SNP) | VAF 175/672 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.485); catalogued as rs180878214; called by muse, mutect2, varscan2
- OR5A2 | c.851C>G p.P284R | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119800; called by muse, mutect2, varscan2
- OR5B12 | c.601del p.V201Wfs*11 | Frame Shift Del (DEL) | VAF 22/147 reads (15%) | catalogued as COSV100222519; called by mutect2, pindel, varscan2
- OR5R1 | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 97/352 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as rs200481477; called by muse, mutect2, varscan2
- OR8I2 | c.559T>G p.S187A | Missense Mutation (SNP) | VAF 56/391 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV56170352; called by muse, mutect2, varscan2
- OR9A4 | c.520G>T p.V174L | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV71885269; called by muse, mutect2, varscan2
- PCDHB7 | c.2225C>A p.T742N | Missense Mutation (SNP) | VAF 145/399 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs781787452; called by muse, mutect2, varscan2
- PCLO | c.13707A>T p.E4569D | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100426661; called by muse, mutect2, varscan2
- PCLO | c.6808G>T p.A2270S | Missense Mutation (SNP) | VAF 71/319 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.053); catalogued as COSV100430365; called by muse, mutect2, varscan2
- PIK3CG | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.279); catalogued as rs1189118505, COSV63248762, COSV63250737; called by muse, mutect2, varscan2
- PITX2 | c.227C>G p.A76G (on ENST00000354925 / NM_001204397.1; = p.A83G on NM_000325.6) | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs763095137; called by muse, mutect2, varscan2
- PLCG2 | c.95G>T p.S32I | Missense Mutation (SNP) | VAF 127/409 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.558); catalogued as COSV63876837; called by muse, mutect2, varscan2
- PLPP4 | c.685C>A p.L229M | Missense Mutation (SNP) | VAF 99/354 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV64827209; called by muse, mutect2, varscan2
- PLXDC2 | c.1189G>T p.G397* | Nonsense Mutation (SNP) | VAF 102/543 reads (19%) | catalogued as COSV101022816; called by muse, mutect2, varscan2
- POTEI | c.280C>A p.L94I | Missense Mutation (SNP) | VAF 227/942 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs756800503; called by muse, mutect2, varscan2
- PRAMEF1 | c.422T>C p.M141T | Missense Mutation (SNP) | VAF 64/625 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1063765; called by muse, mutect2, varscan2
- PRNP | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 112/489 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV65173857; called by muse, mutect2, varscan2
- PRSS37 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs766010613; called by muse, mutect2, varscan2
- RAG1 | c.2690G>C p.R897P | Missense Mutation (SNP) | VAF 35/225 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55026579; called by muse, mutect2, varscan2
- RETREG1 | c.1157C>A p.P386Q (on ENST00000306320 / NM_001034850.2; = p.P245Q on NM_019000.4) | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1450692898; called by muse, mutect2, varscan2
- RNF128 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 75/143 reads (52%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV55251478; called by muse, mutect2, varscan2
- RTTN | c.5638G>T p.A1880S | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs758145815; called by muse, mutect2, varscan2
- RUNX1T1 | c.1537G>T p.E513* (on ENST00000265814 / NM_001198628.1; = p.E486* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/95 reads (34%) | catalogued as COSV56138839, COSV56159248; called by muse, mutect2, varscan2
- RYR2 | c.12290A>T p.N4097I | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM045194; called by muse, mutect2, varscan2
- SCTR | c.589G>C p.A197P | Missense Mutation (SNP) | VAF 95/488 reads (19%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.979); catalogued as COSV99191522; called by muse, mutect2, varscan2
- SEMA3G | c.1909G>A p.E637K | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as COSV51596698; called by muse, varscan2
- SGPP1 | c.1189A>G p.I397V | Missense Mutation (SNP) | VAF 78/319 reads (24%) | SIFT tolerated (0.74); PolyPhen benign (0.113); catalogued as rs1478963963; called by muse, mutect2, varscan2
- SI | c.3211C>A p.P1071T | Missense Mutation (SNP) | VAF 102/426 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52270121, COSV52279035; called by muse, mutect2, varscan2
- SLC38A6 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 97/485 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1419672066; called by muse, mutect2, varscan2
- SLC39A4 | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 94/320 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.306); catalogued as rs576373907, CM1313104; called by muse, mutect2, varscan2
- SLC6A6 | c.1693C>T p.L565F | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.03); catalogued as rs1466454467; called by muse, mutect2, varscan2
- SLCO6A1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1256562725; called by muse, mutect2, varscan2
- SLCO6A1 | c.1532C>A p.S511* | Nonsense Mutation (SNP) | VAF 130/309 reads (42%) | catalogued as COSV65807924; called by muse, mutect2, varscan2
- SNTG2 | c.889-1G>T p.X297_splice | Splice Site (SNP) | VAF 60/200 reads (30%) | catalogued as rs774503752; called by muse, mutect2, varscan2
- SNX29 | c.2200C>T p.R734W | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs754867622, COSV100030598, COSV60069600; called by muse, mutect2, varscan2
- SON | c.2104A>T p.T702S | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.172); catalogued as rs1442808713; called by muse, mutect2, varscan2
- SOST | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as rs1325102301; called by muse, mutect2, varscan2
- SPATA31A6 | c.1088T>C p.L363S | Missense Mutation (SNP) | VAF 252/491 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs757558656; called by muse, mutect2, varscan2
- SPATA31A6 | c.3742C>A p.H1248N | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100253004; called by mutect2, varscan2
- SSTR5 | c.788C>A p.P263H | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99559704; called by muse, mutect2, varscan2
- STYXL2 | c.1711G>A p.G571S | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.187); catalogued as rs757874206; called by muse, mutect2, varscan2
- SVIL | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 115/447 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs373559551; called by muse, mutect2, varscan2
- SYNE1 | c.3221G>T p.C1074F (on ENST00000367255 / NM_182961.4; = p.C1081F on NM_033071.3) | Missense Mutation (SNP) | VAF 121/345 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99555928; called by muse, mutect2, varscan2
- SYT16 | c.1435-1G>T p.X479_splice | Splice Site (SNP) | VAF 76/295 reads (26%) | catalogued as COSV101413665; called by muse, mutect2, varscan2
- SYT4 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 94/346 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as rs748705825; called by muse, mutect2, varscan2
- SYTL5 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 198/391 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV52897967; called by muse, mutect2, varscan2
- TAF1L | c.561del p.S188Pfs*40 | Frame Shift Del (DEL) | VAF 108/379 reads (28%) | catalogued as COSV54266544; called by mutect2, pindel, varscan2
- TBX3 | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 314/702 reads (45%) | catalogued as COSV57469802, COSV57471521; called by muse, mutect2, varscan2
- TENM1 | c.4555C>G p.R1519G | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64431715; called by muse, mutect2, varscan2
- TENM2 | c.656C>A p.S219Y | Missense Mutation (SNP) | VAF 141/454 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.99); catalogued as rs777362521; called by muse, mutect2, varscan2
- TENM2 | c.2146T>C p.Y716H (on ENST00000518659 / NM_001122679.2; = p.Y484H on NM_001080428.3) | Missense Mutation (SNP) | VAF 233/572 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1165752711; called by muse, mutect2, varscan2
- TEP1 | c.5920G>T p.A1974S | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.662); catalogued as rs752099970, COSV52988568; called by muse, mutect2, varscan2
- TEP1 | c.5732G>A p.W1911* | Nonsense Mutation (SNP) | VAF 53/205 reads (26%) | catalogued as COSV99401976; called by muse, mutect2, varscan2
- TICAM1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 74/143 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1005476424, COSV50234121; called by muse, mutect2, varscan2
- TKTL2 | c.1147C>G p.R383G | Missense Mutation (SNP) | VAF 243/1042 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99761410; called by muse, mutect2, varscan2
- TMEM132E | c.1497G>T p.Q499H (on ENST00000321639; = p.Q589H on NM_001304438.2) | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58701728; called by muse, mutect2, varscan2
- TMPRSS15 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 49/324 reads (15%) | catalogued as COSV53040485; called by muse, mutect2, varscan2
- TP53 | c.677del p.G226Afs*21 | Frame Shift Del (DEL) | VAF 95/331 reads (29%) | catalogued as COSV52797216, COSV52965428, COSV53510385; called by mutect2, pindel*, varscan2
- TRHDE | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1358501347; called by muse, mutect2, varscan2
- TRIM51 | c.148G>T p.A50S | Missense Mutation (SNP) | VAF 74/505 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.175); catalogued as rs1188347492, COSV99791961; called by muse, mutect2, varscan2
- TRIM60 | c.470G>C p.R157P | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV100594054, COSV61971699; called by muse, mutect2, varscan2
- TRIOBP | c.2603C>T p.S868L | Missense Mutation (SNP) | VAF 23/740 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60384618; called by muse, mutect2
- TRPM2 | c.2345del p.G782Afs*20 | Frame Shift Del (DEL) | VAF 30/168 reads (18%) | catalogued as COSV100309352; called by mutect2, pindel, varscan2
- TSPAN33 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.086); catalogued as rs752060252; called by muse, mutect2, varscan2
- TTN | c.2841+1G>T p.X947_splice (on ENST00000591111; = p.X901_splice on NM_003319.4) | Splice Site (SNP) | VAF 155/699 reads (22%) | catalogued as COSV60206457; called by muse, mutect2, varscan2
- UGT2B10 | c.665G>C p.W222S | Missense Mutation (SNP) | VAF 53/192 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as rs779971456, COSV99607708; called by muse, mutect2
- UQCRC1 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs766616723; called by muse, mutect2, varscan2
- USP17L2 | c.1399C>A p.H467N | Missense Mutation (SNP) | VAF 226/804 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV61555513, COSV61555774; called by muse, mutect2, varscan2
- USP31 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1255427660; called by muse, mutect2, varscan2
- UTF1 | c.884C>G p.P295R | Missense Mutation (SNP) | VAF 47/269 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs931549931, COSV100444105; called by muse, mutect2, varscan2
- VPS26A | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs372476544; called by muse, mutect2, varscan2
- VWCE | c.2184T>A p.C728* | Nonsense Mutation (SNP) | VAF 48/450 reads (11%) | catalogued as rs779698167; called by muse, mutect2, varscan2
- WDR49 | c.870del p.L292Yfs*37 (on ENST00000308378 / NM_001366158.1; = p.L633Yfs*37 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 62/265 reads (23%) | catalogued as COSV57706589; called by mutect2, pindel, varscan2
- XAGE3 | c.81G>T p.L27= | Splice Region (SNP) | VAF 70/289 reads (24%) | catalogued as COSV100655621; called by muse, mutect2, varscan2
- XIRP2 | c.8954C>G p.S2985W (on ENST00000628543; = p.S3160W on NM_152381.6) | Missense Mutation (SNP) | VAF 112/423 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs1348177382, COSV54704762; called by muse, mutect2, varscan2
- XKR3 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV58886309, COSV58888038; called by muse, mutect2, varscan2
- ZEB2 | c.1274C>A p.P425H | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356066; called by muse, mutect2, varscan2
- ZFAT | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 100/458 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV104428247; called by muse, mutect2, varscan2
- ZFHX4 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 106/340 reads (31%) | catalogued as COSV50790861; called by muse, mutect2, varscan2
- ZNF521 | c.738G>C p.Q246H | Missense Mutation (SNP) | VAF 110/429 reads (26%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.673); catalogued as rs988403953; called by muse, mutect2, varscan2
- ZNF532 | c.3564A>T p.Q1188H | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); catalogued as COSV60175980; called by muse, mutect2, varscan2
- ZNF804B | c.3833C>A p.P1278Q | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.123); catalogued as COSV100302655; called by muse, varscan2
- ZSCAN31 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV60180554; called by muse, mutect2, varscan2
- AASS | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 199/715 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ABCA13 | c.3976G>T p.E1326* | Nonsense Mutation (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- ABCB5 | c.1768G>T p.D590Y (on ENST00000404938 / NM_001163941.2; = p.D145Y on NM_178559.6) | Missense Mutation (SNP) | VAF 71/330 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ABCC12 | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 157/516 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCC5 | c.1498G>T p.D500Y | Missense Mutation (SNP) | VAF 134/437 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AC138647.1 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- AC244197.3 | c.610G>T p.G204* | Nonsense Mutation (SNP) | VAF 123/184 reads (67%) | called by muse, mutect2, varscan2
- ACTG2 | c.452G>C p.G151A | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2
- ACVR2B | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 145/571 reads (25%) | called by muse, mutect2, varscan2
- ADAD2 | c.1373C>A p.P458H (on ENST00000315906 / NM_001145400.2; = p.P540H on NM_139174.4) | Missense Mutation (SNP) | VAF 74/230 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMDEC1 | c.1142G>T p.S381I | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ADAMTS20 | c.4902T>A p.Y1634* | Nonsense Mutation (SNP) | VAF 96/343 reads (28%) | called by muse, mutect2, varscan2
- ADCY2 | c.1603T>A p.F535I | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- ADD2 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.4584G>T p.K1528N | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ADGRL3 | c.4213G>T p.G1405C (on ENST00000506720 / NM_001322402.2; = p.G1294C on NM_015236.6) | Missense Mutation (SNP) | VAF 97/418 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ADGRV1 | c.12331G>A p.V4111M | Missense Mutation (SNP) | VAF 145/346 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AFAP1L1 | c.1306C>A p.R436S | Missense Mutation (SNP) | VAF 202/433 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AGBL4 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- AGO1 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 67/446 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AHNAK2 | c.7636C>G p.Q2546E | Missense Mutation (SNP) | VAF 134/541 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ALCAM | c.1468C>A p.Q490K | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANKMY1 | c.1882G>C p.D628H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- ANKRD17 | c.6381G>T p.Q2127H | Missense Mutation (SNP) | VAF 167/732 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- ANKRD53 | c.68G>A p.G23E | Missense Mutation (SNP) | VAF 93/337 reads (28%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- ANKS1A | c.2204A>T p.E735V | Missense Mutation (SNP) | VAF 53/221 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- ANKS1B | c.1507A>C p.T503P | Missense Mutation (SNP) | VAF 84/351 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANKS6 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA2 | c.933C>G p.Y311* | Nonsense Mutation (SNP) | VAF 77/286 reads (27%) | called by muse, mutect2, varscan2
- ASB3 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 74/279 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- ASTN1 | c.1024T>A p.F342I | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ATAD3A | c.1282G>T p.D428Y | Missense Mutation (SNP) | VAF 89/433 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG9B | c.885A>T p.Q295H | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- ATP13A4 | c.2428C>G p.L810V | Missense Mutation (SNP) | VAF 107/459 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ATP6V0A4 | c.93G>T p.E31D | Missense Mutation (SNP) | VAF 135/611 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- BCHE | c.1795dup p.C599Lfs*39 | Frame Shift Ins (INS) | VAF 53/234 reads (23%) | called by mutect2, pindel, varscan2
- BLK | c.733A>G p.R245G | Missense Mutation (SNP) | VAF 68/672 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- BLK | c.1430C>A p.P477H | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BOD1L1 | c.7436G>T p.G2479V | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- BTBD11 | c.1059C>G p.H353Q | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf56 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by mutect2, varscan2
- CACNA1C | c.3357-1G>T p.X1119_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- CACNA1D | c.1892+1G>T p.X631_splice (on ENST00000350061 / NM_001128840.3; = p.X651_splice on NM_000720.4) | Splice Site (SNP) | VAF 105/771 reads (14%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAPN13 | c.1536+5G>T | Splice Region (SNP) | VAF 84/400 reads (21%) | called by muse, mutect2, varscan2
- CASS4 | c.2135T>A p.V712E | Missense Mutation (SNP) | VAF 98/400 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CBWD1 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC137 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 118/340 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC141 | c.3225C>A p.D1075E | Missense Mutation (SNP) | VAF 86/407 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CCDC168 | c.4811C>A p.T1604K | Missense Mutation (SNP) | VAF 111/295 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CCDC180 | c.4730C>A p.T1577N | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CCDC78 | c.513G>A p.W171* | Nonsense Mutation (SNP) | VAF 128/475 reads (27%) | called by muse, mutect2, varscan2
- CCNL2 | c.865-2A>T p.X289_splice | Splice Site (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- CD109 | c.4144G>A p.V1382M | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CD300C | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 106/558 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CD79B | c.430G>C p.G144R | Missense Mutation (SNP) | VAF 104/433 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC14C | c.1120A>T p.K374* (on ENST00000428251; = p.K267* on NM_152627.3) | Nonsense Mutation (SNP) | VAF 44/400 reads (11%) | called by muse, mutect2, varscan2
- CDC42BPB | c.5080C>T p.P1694S | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH10 | c.1336C>A p.P446T | Missense Mutation (SNP) | VAF 117/425 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- CDH13 | c.607T>A p.L203M | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDH2 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 69/515 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- CDH2 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 89/338 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH7 | c.386C>A p.T129N | Missense Mutation (SNP) | VAF 200/946 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CES2 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- CFAP43 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 55/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP44 | c.5128G>T p.V1710L | Missense Mutation (SNP) | VAF 55/403 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CFAP65 | c.4102G>T p.A1368S | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- CHSY3 | c.1294A>T p.S432C | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CIBAR2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- CLCN1 | c.2774C>A p.A925D | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC14A | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CLGN | c.501G>T p.L167= | Splice Region (SNP) | VAF 58/233 reads (25%) | called by muse, mutect2, varscan2
- CLMP | c.813T>A p.N271K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CMTR2 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- CNBD1 | c.606C>A p.D202E | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CNKSR2 | c.1092-1G>T p.X364_splice | Splice Site (SNP) | VAF 48/87 reads (55%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.2246A>T p.Y749F | Missense Mutation (SNP) | VAF 196/734 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COBL | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 42/384 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COL11A1 | c.2732C>A p.P911H | Missense Mutation (SNP) | VAF 92/794 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A2 | c.1817C>A p.S606* (on ENST00000341947 / NM_080680.3; = p.S499* on NM_080679.2) | Nonsense Mutation (SNP) | VAF 84/332 reads (25%) | called by muse, mutect2, varscan2
- COL6A5 | c.2791C>A p.H931N | Missense Mutation (SNP) | VAF 68/564 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.109); called by muse, varscan2
- COL6A5 | c.4975G>T p.G1659C | Missense Mutation (SNP) | VAF 138/581 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.6780T>A p.S2260R (on ENST00000312481; = p.S2256R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- COL6A6 | c.2267G>C p.G756A | Missense Mutation (SNP) | VAF 129/543 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL8A2 | c.92G>T p.G31V | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- CPA1 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 54/238 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CPE | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- CR1 | c.3727del p.Q1243Rfs*13 | Frame Shift Del (DEL) | VAF 82/303 reads (27%) | called by mutect2, pindel, varscan2
- CR2 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRACD | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 110/443 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CRYGN | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CSK | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- CSMD1 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 143/494 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD2 | c.6692C>A p.P2231H | Missense Mutation (SNP) | VAF 106/304 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- CSMD2 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 72/238 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSMD3 | c.7510C>A p.Q2504K (on ENST00000297405 / NM_001363185.1; = p.Q2400K on NM_052900.3) | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.593); called by muse, mutect2
- CSMD3 | c.4208G>A p.W1403* (on ENST00000297405 / NM_001363185.1; = p.W1299* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 54/329 reads (16%) | called by muse, mutect2, varscan2
- CSMD3 | c.3406C>A p.L1136M (on ENST00000297405 / NM_001363185.1; = p.L1032M on NM_052900.3) | Missense Mutation (SNP) | VAF 160/667 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CSN2 | c.352C>A p.L118I | Missense Mutation (SNP) | VAF 188/914 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSPG4 | c.331_332del p.T111Cfs*79 | Frame Shift Del (DEL) | VAF 32/210 reads (15%) | called by pindel, varscan2
- CSRP2 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 54/480 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTDP1 | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 23/74 reads (31%) | called by muse, mutect2, varscan2
- CTNND2 | c.1213C>A p.H405N | Missense Mutation (SNP) | VAF 189/876 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CUBN | c.4529G>T p.C1510F | Missense Mutation (SNP) | VAF 94/468 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- D2HGDH | c.1031G>C p.G344A | Missense Mutation (SNP) | VAF 118/483 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DAAM2 | c.2276T>A p.L759Q | Missense Mutation (SNP) | VAF 39/289 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DACH2 | c.1330G>T p.G444* | Nonsense Mutation (SNP) | VAF 130/283 reads (46%) | called by muse, mutect2, varscan2
- DALRD3 | c.1329+2T>A p.X443_splice (on ENST00000341949 / NM_001009996.3; = p.X276_splice on NM_018114.5) | Splice Site (SNP) | VAF 25/82 reads (30%) | called by muse, mutect2, varscan2
- DBX1 | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCAF4L2 | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 63/444 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DCC | c.3401C>A p.A1134D | Missense Mutation (SNP) | VAF 219/800 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DCDC1 | c.1522G>A p.V508I | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- DDAH2 | c.487A>T p.T163S | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.703); called by muse, mutect2
- DDX19B | c.743T>A p.I248K | Missense Mutation (SNP) | VAF 102/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DKK2 | c.65T>A p.M22K | Missense Mutation (SNP) | VAF 144/709 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DLGAP1 | c.2920C>T p.Q974* | Nonsense Mutation (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- DLGAP2 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- DLGAP3 | c.1083A>T p.K361N | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DLGAP3 | c.527C>A p.S176Y | Missense Mutation (SNP) | VAF 51/318 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DNAH10 | c.5106G>T p.M1702I (on ENST00000409039; = p.M1641I on NM_207437.3) | Missense Mutation (SNP) | VAF 287/648 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- DNAH2 | c.4461G>C p.M1487I | Missense Mutation (SNP) | VAF 125/351 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH5 | c.9789G>T p.K3263N | Missense Mutation (SNP) | VAF 226/660 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAH9 | c.3577-1G>T p.X1193_splice | Splice Site (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- DNAH9 | c.9181G>T p.E3061* | Nonsense Mutation (SNP) | VAF 74/243 reads (30%) | called by muse, mutect2, varscan2
- DNAH9 | c.11071G>C p.D3691H | Missense Mutation (SNP) | VAF 76/266 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- DNTTIP2 | c.602G>T p.R201I | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- DPH5 | c.758_768del p.I253Rfs*20 | Frame Shift Del (DEL) | VAF 93/784 reads (12%) | called by mutect2, pindel
- DPP6 | c.681G>T p.G227= (on ENST00000377770 / NM_001364500.2; = p.G165= on NM_001936.5) | Splice Region (SNP) | VAF 78/326 reads (24%) | called by muse, mutect2, varscan2
- DPYS | c.1232C>A p.T411K | Missense Mutation (SNP) | VAF 145/459 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DPYS | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 130/692 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DST | c.15280C>A p.Q5094K (on ENST00000361203 / NM_001374722.1; = p.Q2682K on NM_015548.5) | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DST | c.14647G>T p.E4883* (on ENST00000361203 / NM_001374722.1; = p.E2471* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 41/330 reads (12%) | called by muse, mutect2, varscan2
- DST | c.10158+2T>G p.X3386_splice | Splice Site (SNP) | VAF 21/71 reads (30%) | called by muse, mutect2
- DST | c.7294A>G p.T2432A | Missense Mutation (SNP) | VAF 123/344 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DST | c.4630G>T p.D1544Y (on ENST00000361203 / NM_001374722.1; = p.D1218Y on NM_015548.5) | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DYNC2H1 | c.6211G>A p.D2071N | Missense Mutation (SNP) | VAF 86/511 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EDN2 | c.345G>T p.W115C | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- EIF1 | c.235dup p.Y79Lfs*10 | Frame Shift Ins (INS) | VAF 58/313 reads (19%) | called by mutect2, varscan2
- EIF1 | c.237_239del p.Y79_G80delins* | Nonsense Mutation (DEL) | VAF 62/312 reads (20%) | called by mutect2, pindel*, varscan2
- ELAPOR2 | c.548G>T p.R183L (on ENST00000450689 / NM_001142749.3; = p.R16L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/441 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- EMILIN1 | c.1517A>T p.D506V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- ENO1 | c.287A>T p.E96V | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); called by muse, varscan2
- EPHA10 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 67/215 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- EPHA6 | c.2239C>T p.P747S (on ENST00000389672 / NM_001080448.3; = p.P139S on NM_173655.4) | Missense Mutation (SNP) | VAF 62/226 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAM13A | c.1195G>C p.A399P | Missense Mutation (SNP) | VAF 155/689 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM171A1 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 176/739 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM184B | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FARS2 | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAT4 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 28/215 reads (13%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FBH1 | c.1950G>T p.Q650H (on ENST00000362091 / NM_178150.3; = p.Q701H on NM_032807.4) | Missense Mutation (SNP) | VAF 118/528 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FCRL1 | c.694C>G p.L232V | Missense Mutation (SNP) | VAF 266/660 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.171); called by muse, mutect2
- FHDC1 | c.1966G>T p.G656C | Missense Mutation (SNP) | VAF 144/508 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- FIP1L1 | c.445G>T p.G149* | Nonsense Mutation (SNP) | VAF 103/459 reads (22%) | called by muse, mutect2, varscan2
- FLG | c.8698C>T p.H2900Y | Missense Mutation (SNP) | VAF 504/2193 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FNDC7 | c.1795T>A p.C599S | Missense Mutation (SNP) | VAF 90/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FSTL5 | c.963C>A p.C321* | Nonsense Mutation (SNP) | VAF 138/494 reads (28%) | called by muse, mutect2, varscan2
- FZD10 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 103/212 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FZD9 | c.786C>G p.Y262* | Nonsense Mutation (SNP) | VAF 27/173 reads (16%) | called by muse, mutect2, varscan2
- GABRA1 | c.149T>G p.L50R | Missense Mutation (SNP) | VAF 187/483 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GABRA1 | c.256-3T>C | Splice Region (SNP) | VAF 141/372 reads (38%) | called by muse, mutect2, varscan2
- GAL3ST1 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- GANAB | c.1994A>T p.Q665L | Missense Mutation (SNP) | VAF 54/354 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GAS2 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- GASK1A | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GBF1 | c.4366G>C p.E1456Q (on ENST00000369983 / NM_001377137.1; = p.E1455Q on NM_004193.3) | Missense Mutation (SNP) | VAF 62/414 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GBP5 | c.190+1G>T p.X64_splice | Splice Site (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- GCM2 | c.677del p.P226Lfs*22 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- GET3 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GNL2 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- GOLGA5 | c.1499del p.E500Gfs*22 | Frame Shift Del (DEL) | VAF 102/591 reads (17%) | called by mutect2, pindel, varscan2
- GPR4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- GRM1 | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 167/472 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GRM7 | c.452T>A p.V151D | Missense Mutation (SNP) | VAF 27/220 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRM7 | c.2503G>T p.V835L | Missense Mutation (SNP) | VAF 173/566 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- H2AP | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 109/210 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- HAVCR2 | c.119A>T p.Y40F | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HDAC4 | c.2374-2A>T p.X792_splice | Splice Site (SNP) | VAF 97/369 reads (26%) | called by muse, mutect2, varscan2
- HECTD1 | c.2188A>G p.R730G | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- HELZ2 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- HEPH | c.3373G>C p.A1125P (on ENST00000343002; = p.A858P on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 237/474 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- HERC2 | c.7588G>C p.E2530Q | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, varscan2
- HERC2 | c.2716_2717insA p.R906Qfs*15 | Frame Shift Ins (INS) | VAF 40/288 reads (14%) | called by pindel, varscan2
- HIVEP2 | c.7217A>T p.H2406L | Missense Mutation (SNP) | VAF 131/479 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- HLA-DQB1 | c.417G>T p.E139D | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- HLA-DQB2 | c.402G>T p.E134D | Missense Mutation (SNP) | VAF 19/330 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); called by muse, mutect2
- HLX | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN2 | c.12724C>A p.P4242T | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HNRNPUL2 | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HOXD11 | c.790dup p.Q264Pfs*25 | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | called by mutect2, varscan2
- HPS6 | c.2141A>T p.D714V | Missense Mutation (SNP) | VAF 43/306 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- HYAL4 | c.418G>T p.G140* | Nonsense Mutation (SNP) | VAF 33/153 reads (22%) | called by muse, mutect2, varscan2
- IFT140 | c.2275C>G p.L759V | Missense Mutation (SNP) | VAF 144/632 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IGSF1 | c.3799C>A p.L1267I | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- IL10RA | c.97T>A p.W33R | Missense Mutation (SNP) | VAF 88/560 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- IL17RD | c.2139G>T p.K713N | Missense Mutation (SNP) | VAF 87/540 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INHBC | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 386/730 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IPP | c.233T>C p.V78A | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IQGAP2 | c.3118G>C p.V1040L | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ISLR | c.829A>T p.I277F | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ITGA2B | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAX | c.3091C>G p.R1031G | Missense Mutation (SNP) | VAF 76/265 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- ITK | c.1731G>T p.L577F | Missense Mutation (SNP) | VAF 278/678 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITPR2 | c.5164A>T p.K1722* | Nonsense Mutation (SNP) | VAF 140/444 reads (32%) | called by muse, mutect2, varscan2
- JPH3 | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- KANK4 | c.2149G>T p.G717W | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KANSL1L | c.772G>C p.G258R | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT5 | c.1469A>T p.K490M | Missense Mutation (SNP) | VAF 47/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KCNB1 | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 47/191 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCP | c.4120T>C p.Y1374H (on ENST00000620378; = p.Y1498H on NM_001366122.1) | Missense Mutation (SNP) | VAF 166/606 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KIF1A | c.3225G>T p.E1075D | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- KIF27 | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KIF2C | c.1550A>T p.N517I | Missense Mutation (SNP) | VAF 41/257 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLC4 | c.373G>T p.G125C | Missense Mutation (SNP) | VAF 86/502 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- KLK4 | c.134A>T p.Q45L | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KMT2D | c.9095A>T p.E3032V | Missense Mutation (SNP) | VAF 290/613 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KMT2D | c.9052G>T p.V3018L | Missense Mutation (SNP) | VAF 219/456 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- KRTAP7-1 | c.176G>T p.S59I | Missense Mutation (SNP) | VAF 56/430 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.238); called by muse, mutect2
- L2HGDH | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- L3MBTL3 | c.1518+2T>A p.X506_splice | Splice Site (SNP) | VAF 61/195 reads (31%) | called by muse, mutect2, varscan2
- LAMB1 | c.5315T>A p.L1772Q | Missense Mutation (SNP) | VAF 68/305 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMB3 | c.1592G>C p.C531S | Missense Mutation (SNP) | VAF 147/415 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMC1 | c.611dup p.L204Ffs*4 | Frame Shift Ins (INS) | VAF 59/227 reads (26%) | called by mutect2, pindel, varscan2
- LCE3C | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 117/218 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- LCT | c.4692del p.Y1565Tfs*7 | Frame Shift Del (DEL) | VAF 47/402 reads (12%) | called by mutect2, pindel, varscan2
- LEF1 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LGR6 | c.997C>T p.L333= (on ENST00000367278 / NM_001017403.1; = p.L281= on NM_021636.3) | Splice Region (SNP) | VAF 53/155 reads (34%) | called by muse, mutect2, varscan2
- LLCFC1 | c.282G>T p.M94I (on ENST00000458732; = p.M63I on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/736 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- LMX1A | c.497-1G>C p.X166_splice | Splice Site (SNP) | VAF 59/212 reads (28%) | called by muse, varscan2
- LNPK | c.813-6G>T | Splice Region (SNP) | VAF 24/142 reads (17%) | called by muse, mutect2, varscan2
- LNX2 | c.1288A>T p.I430F | Missense Mutation (SNP) | VAF 95/371 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIF1 | c.918dup p.V307Cfs*2 | Frame Shift Ins (INS) | VAF 52/205 reads (25%) | called by mutect2, pindel, varscan2
- LRP1B | c.5372G>C p.W1791S | Missense Mutation (SNP) | VAF 133/593 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRP1B | c.1471C>G p.L491V | Missense Mutation (SNP) | VAF 128/685 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRP2 | c.5025C>A p.N1675K | Missense Mutation (SNP) | VAF 46/456 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- LRRC3B | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LSAMP | c.999C>A p.C333* | Nonsense Mutation (SNP) | VAF 120/525 reads (23%) | called by muse, mutect2, varscan2
- LSM14A | c.1345G>T p.E449* | Nonsense Mutation (SNP) | VAF 83/217 reads (38%) | called by muse, mutect2, varscan2
- LTK | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- LZTR1 | c.320+8G>T | Splice Region (SNP) | VAF 79/211 reads (37%) | called by muse, mutect2, varscan2
- MAGEB2 | c.956T>A p.V319D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MAGEB6B | c.682C>A p.Q228K | Missense Mutation (SNP) | VAF 92/157 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC1 | c.178_179insT p.G60Vfs*13 | Frame Shift Ins (INS) | VAF 35/311 reads (11%) | called by pindel, varscan2
- MAMLD1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 82/112 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN1A2 | c.576G>T p.W192C | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCC | c.859G>C p.V287L | Missense Mutation (SNP) | VAF 91/197 reads (46%) | SIFT tolerated (0.76); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MEP1A | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MFAP5 | c.177G>T p.L59F | Missense Mutation (SNP) | VAF 97/317 reads (31%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MMS22L | c.3389A>G p.K1130R | Missense Mutation (SNP) | VAF 129/377 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MOGAT2 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- MORC4 | c.538A>G p.I180V | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPDZ | c.3359G>A p.R1120K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRPS26 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 98/470 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- MTMR12 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC12 | c.3758C>A p.S1253* (on ENST00000379442; = p.S1110* on NM_001164462.1) | Nonsense Mutation (SNP) | VAF 166/1738 reads (10%) | called by muse, varscan2
- MUC2 | c.1953G>T p.E651D | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC5AC | c.1193A>G p.Y398C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYCT1 | c.680C>A p.S227Y | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MYH13 | c.5068G>C p.E1690Q | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH13 | c.1670A>T p.Q557L | Missense Mutation (SNP) | VAF 100/268 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- MYH8 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 145/543 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- N4BP1 | c.2219C>A p.T740K | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NEU4 | c.706T>A p.F236I (on ENST00000391969 / NM_001167602.3; = p.F248I on NM_080741.4) | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2
- NEU4 | c.708C>A p.F236L (on ENST00000391969 / NM_001167602.3; = p.F248L on NM_080741.4) | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- NHLRC3 | c.902C>T p.T301I | Missense Mutation (SNP) | VAF 109/563 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- NLRP10 | c.649A>C p.S217R | Missense Mutation (SNP) | VAF 77/250 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP2 | c.1069G>T p.E357* | Nonsense Mutation (SNP) | VAF 50/141 reads (35%) | called by muse, mutect2, varscan2
- NOBOX | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.45); called by muse, mutect2
- NPAP1 | c.2210_2211delinsCAA p.G737Afs*42 | Frame Shift Ins (INS) | VAF 57/228 reads (25%) | called by pindel, varscan2*
- NPC1L1 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 70/618 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.558); called by muse, varscan2
- NPHP4 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- NQO2 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRDE2 | c.902A>T p.D301V | Missense Mutation (SNP) | VAF 111/482 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NRXN2 | c.2992G>A p.D998N | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NSD3 | c.3197del p.N1066Tfs*16 | Frame Shift Del (DEL) | VAF 34/267 reads (13%) | called by mutect2, pindel, varscan2
- NTM | c.694G>T p.G232C | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- NTSR1 | c.961G>T p.V321L | Missense Mutation (SNP) | VAF 89/435 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- NWD2 | c.662A>T p.K221M | Missense Mutation (SNP) | VAF 41/215 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NYAP2 | c.811A>G p.M271V | Missense Mutation (SNP) | VAF 91/403 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- NYNRIN | c.5335G>C p.A1779P | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- OR10D3 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 65/564 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- OR10J3 | c.209C>G p.S70C | Missense Mutation (SNP) | VAF 93/713 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR11H2 | c.366G>T p.M122I (on ENST00000556246; = p.M133I on NM_001197287.1) | Missense Mutation (SNP) | VAF 82/963 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- OR1J1 | c.58C>G p.R20G | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR2T27 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR4C15 | c.958dup p.L320Pfs*2 (on ENST00000314644; = p.L266Pfs*2 on NM_001001920.2) | Frame Shift Ins (INS) | VAF 67/446 reads (15%) | called by mutect2, pindel, varscan2
- OR4K2 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 60/648 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2
- OR4Q3 | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 71/371 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR51C1P | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR56B4 | c.340T>C p.F114L | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5I1 | c.795C>A p.S265R | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- OR6B2 | c.494G>T p.S165I | Missense Mutation (SNP) | VAF 60/383 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OR8D2 | c.373G>C p.A125P | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR9I1 | c.790T>A p.S264T | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- OSBPL6 | c.801T>A p.H267Q | Missense Mutation (SNP) | VAF 56/282 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTOG | c.8180A>G p.Y2727C | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- OTOL1 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P2RY12 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 159/751 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- PADI3 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 94/445 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, varscan2
- PADI6 | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- PALM | c.666C>A p.N222K | Missense Mutation (SNP) | VAF 141/261 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.523A>C p.K175Q (on ENST00000259318 / NM_001136562.3; = p.K406Q on NM_007203.5) | Missense Mutation (SNP) | VAF 61/409 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PANX1 | c.254G>T p.W85L | Missense Mutation (SNP) | VAF 58/432 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PARP14 | c.4529A>T p.E1510V | Missense Mutation (SNP) | VAF 59/189 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PCARE | c.811del p.L271Yfs*41 | Frame Shift Del (DEL) | VAF 30/144 reads (21%) | called by mutect2, pindel, varscan2
- PCDH10 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 88/304 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PCDH17 | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 124/349 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PCDHGB3 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 93/242 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- PCLO | c.4600G>T p.G1534C | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PCLO | c.2786G>T p.G929V | Missense Mutation (SNP) | VAF 97/389 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.2785G>T p.G929W | Missense Mutation (SNP) | VAF 96/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDAP1 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE1C | c.494A>G p.D165G | Missense Mutation (SNP) | VAF 59/224 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PDE3B | c.1029+5G>T | Splice Region (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- PDHA2 | c.1139C>A p.P380Q | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PDIA6 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 45/401 reads (11%) | SIFT tolerated (0.76); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- PEX10 | c.301G>T p.V101F | Missense Mutation (SNP) | VAF 67/243 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PEX5L | c.912C>G p.N304K | Missense Mutation (SNP) | VAF 92/381 reads (24%) | SIFT tolerated (0.98); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PEX5L | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 54/181 reads (30%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGBD1 | c.509G>A p.C170Y | Missense Mutation (SNP) | VAF 72/393 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIEZO2 | c.1373C>A p.S458Y | Missense Mutation (SNP) | VAF 145/622 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PIKFYVE | c.1746C>G p.F582L | Missense Mutation (SNP) | VAF 73/579 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PIWIL4 | c.2084T>A p.V695E | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PKHD1 | c.11336C>T p.P3779L | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCB1 | c.448G>C p.A150P | Missense Mutation (SNP) | VAF 134/470 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PLCB2 | c.1239-3C>A | Splice Region (SNP) | VAF 52/135 reads (39%) | called by muse, mutect2, varscan2
- PLCH2 | c.3765G>T p.K1255N | Missense Mutation (SNP) | VAF 43/352 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PLXNA2 | c.1232A>T p.Q411L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- PLXNA4 | c.563C>A p.A188E | Missense Mutation (SNP) | VAF 141/672 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PLXNB1 | c.1477G>T p.A493S | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- POLR2B | c.1160A>T p.H387L | Missense Mutation (SNP) | VAF 90/395 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PORCN | c.898del p.E300Kfs*14 (on ENST00000326194 / NM_203475.3; = p.E289Kfs*14 on NM_022825.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 222/539 reads (41%) | called by mutect2, pindel, varscan2
- POTEI | c.2648G>T p.R883L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- POTEJ | c.2929C>A p.Q977K | Missense Mutation (SNP) | VAF 79/919 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PPIAL4D | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 164/2566 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); called by muse, mutect2
- PPP1R3A | c.750A>T p.R250S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PPP4R3C | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 155/320 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRAMEF12 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.222); called by muse, varscan2
- PRDM14 | c.1015C>A p.L339I | Missense Mutation (SNP) | VAF 70/485 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRICKLE1 | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 83/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRKCQ | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 128/627 reads (20%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKG1 | c.941A>T p.D314V | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRL | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- PRLHR | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PROS1 | c.935A>T p.Y312F | Missense Mutation (SNP) | VAF 123/410 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PTPRN2 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PXDNL | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 92/415 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- R3HDML | c.502del p.H168Ifs*78 | Frame Shift Del (DEL) | VAF 14/61 reads (23%) | called by mutect2, pindel, varscan2
- RAB3GAP2 | c.1865G>T p.S622I | Missense Mutation (SNP) | VAF 69/227 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- RANBP10 | c.1554G>T p.L518F | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RANBP6 | c.1561G>C p.V521L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- RBFOX3 | c.318C>G p.I106M | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM23 | c.1206_1220del p.V404_A408del (on ENST00000359890 / NM_001077351.2; = p.V388_A392del on NM_018107.5 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 27/124 reads (22%) | called by mutect2, pindel, varscan2
- RBM5 | c.2183C>T p.A728V | Missense Mutation (SNP) | VAF 117/371 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- RBMX2 | c.827A>G p.H276R | Missense Mutation (SNP) | VAF 188/409 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBMXL3 | c.2074G>A p.G692S | Missense Mutation (SNP) | VAF 104/240 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- RCBTB1 | c.712-2A>T p.X238_splice | Splice Site (SNP) | VAF 43/165 reads (26%) | called by muse, mutect2, varscan2
- RELN | c.1096C>A p.P366T | Missense Mutation (SNP) | VAF 241/904 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RGL2 | c.685C>T p.P229S | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- RIF1 | c.5042A>C p.K1681T | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RNF167 | c.461A>T p.Y154F | Missense Mutation (SNP) | VAF 97/315 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ROBO4 | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRP12 | c.647G>C p.C216S | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- RYR1 | c.12052C>A p.L4018M | Missense Mutation (SNP) | VAF 120/656 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RYR2 | c.11255G>T p.G3752V | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RYR2 | c.11470G>T p.G3824* | Nonsense Mutation (SNP) | VAF 69/206 reads (33%) | called by muse, mutect2, varscan2
- RYR3 | c.2653A>G p.I885V | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- RYR3 | c.13209T>A p.H4403Q (on ENST00000389232; = p.H4404Q on NM_001036.6) | Missense Mutation (SNP) | VAF 38/252 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- SAMD9 | c.4559A>T p.E1520V | Missense Mutation (SNP) | VAF 46/443 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SAMSN1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 67/404 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SAXO1 | c.1061C>A p.P354Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- SCN3B | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 128/432 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN7A | c.1626+1G>T p.X542_splice | Splice Site (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- SCP2D1 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 143/616 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- SEMA5A | c.1376T>C p.I459T | Missense Mutation (SNP) | VAF 234/746 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SEMA6A | c.531T>G p.F177L | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2
- SEMA6A | c.529T>C p.F177L | Missense Mutation (SNP) | VAF 208/458 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2
- SH2D5 | c.944T>A p.L315Q (on ENST00000444387 / NM_001103161.2; = p.L231Q on NM_001103160.2) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- SHANK1 | c.4916C>T p.S1639F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SKIDA1 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC10A2 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 100/342 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- SLC15A2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 114/549 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- SLC19A3 | c.1306A>T p.S436C | Missense Mutation (SNP) | VAF 129/573 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- SLC26A5 | c.1853del p.P618Qfs*2 | Frame Shift Del (DEL) | VAF 147/681 reads (22%) | called by mutect2, pindel, varscan2
- SLC27A2 | c.1684C>T p.Q562* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2
- SLC30A10 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 64/198 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC38A11 | c.712G>C p.D238H (on ENST00000409149 / NM_001351539.1; = p.D216H on NM_173512.2) | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC4A1 | c.2275C>A p.Q759K | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO1B1 | c.619T>A p.L207M | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- SMARCA2 | c.2384G>T p.W795L | Missense Mutation (SNP) | VAF 70/284 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SNCA | c.196G>T p.V66F | Missense Mutation (SNP) | VAF 199/833 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SORCS1 | c.818del p.Y273Sfs*50 | Frame Shift Del (DEL) | VAF 39/349 reads (11%) | called by mutect2, pindel, varscan2
- SORCS3 | c.2234G>C p.C745S | Missense Mutation (SNP) | VAF 81/319 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOS2 | c.3826G>T p.V1276L | Missense Mutation (SNP) | VAF 104/396 reads (26%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPATA22 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
- SPEG | c.908C>G p.P303R | Missense Mutation (SNP) | VAF 68/226 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- SPOPL | c.837+1G>T p.X279_splice | Splice Site (SNP) | VAF 90/369 reads (24%) | called by muse, mutect2, varscan2
- SPTB | c.4364G>T p.S1455I | Missense Mutation (SNP) | VAF 155/641 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- SPTBN5 | c.6205G>T p.E2069* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- SRCAP | c.2131-1G>T p.X711_splice | Splice Site (SNP) | VAF 56/197 reads (28%) | called by muse, mutect2, varscan2
- STAC3 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 43/225 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- STAP2 | c.829+1G>T p.X277_splice | Splice Site (SNP) | VAF 42/244 reads (17%) | called by muse, mutect2, varscan2
- STX17 | c.148A>T p.K50* | Nonsense Mutation (SNP) | VAF 51/351 reads (15%) | called by muse, mutect2, varscan2
- SUGT1 | c.504T>A p.H168Q (on ENST00000343788 / NM_001130912.3; = p.H136Q on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/574 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SULF2 | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 92/347 reads (27%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SULT1B1 | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 48/353 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- TACC2 | c.7702G>T p.E2568* (on ENST00000334433; = p.E646* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 119/392 reads (30%) | called by muse, mutect2, varscan2
- TASOR | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 91/358 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TBC1D21 | c.478+1G>T p.X160_splice | Splice Site (SNP) | VAF 35/137 reads (26%) | called by muse, mutect2, varscan2
- TBC1D4 | c.3331C>T p.Q1111* | Nonsense Mutation (SNP) | VAF 50/223 reads (22%) | called by muse, mutect2, varscan2
- TBCC | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBX15 | c.1237T>A p.Y413N (on ENST00000369429 / NM_001330677.2; = p.Y307N on NM_152380.3) | Missense Mutation (SNP) | VAF 274/945 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- TCAF1 | c.2335T>A p.C779S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- TCF23 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 120/484 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TET2 | c.1643A>T p.Q548L | Missense Mutation (SNP) | VAF 110/536 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TF | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TFCP2L1 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 69/324 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TGM5 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 16/109 reads (15%) | called by muse, mutect2, varscan2
- TGS1 | c.1943G>T p.W648L | Missense Mutation (SNP) | VAF 47/468 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TIAM1 | c.3571C>A p.Q1191K | Missense Mutation (SNP) | VAF 63/392 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TLL1 | c.265C>A p.L89I | Missense Mutation (SNP) | VAF 89/650 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TLR4 | c.795T>A p.N265K (on ENST00000355622 / NM_138554.5; = p.N225K on NM_003266.4) | Missense Mutation (SNP) | VAF 77/644 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- TMA16 | c.376G>T p.G126* | Nonsense Mutation (SNP) | VAF 97/358 reads (27%) | called by muse, mutect2, varscan2
- TMEM108 | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 108/570 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.667); called by muse, varscan2
- TMEM108 | c.640G>C p.G214R | Missense Mutation (SNP) | VAF 96/490 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); called by muse, varscan2
- TMEM229A | c.161G>T p.W54L | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- TMEM241 | c.710A>T p.K237M | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- TMEM62 | c.827C>G p.T276S | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- TMIGD2 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- TMOD2 | c.121C>A p.P41T | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNN | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 73/383 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- TNPO1 | c.1156T>G p.C386G | Missense Mutation (SNP) | VAF 79/152 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, varscan2
- TP63 | c.1464C>A p.N488K | Missense Mutation (SNP) | VAF 81/289 reads (28%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- TPO | c.472del p.C158Afs*51 | Frame Shift Del (DEL) | VAF 124/605 reads (20%) | called by mutect2, pindel, varscan2
- TRAF3IP1 | c.1081A>G p.I361V | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.75); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TRAF7 | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 54/226 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TRERF1 | c.1941del p.V648Cfs*67 | Frame Shift Del (DEL) | VAF 100/402 reads (25%) | called by mutect2, pindel, varscan2
- TRIM22 | c.1454G>T p.W485L | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); called by muse, mutect2
- TRIM29 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM29 | c.132C>A p.N44K | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- TRIM51GP | c.1324C>A p.P442T | Missense Mutation (SNP) | VAF 37/207 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- TRIM58 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TRIM64C | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.07); called by muse, mutect2
- TRIOBP | c.5264A>G p.D1755G | Missense Mutation (SNP) | VAF 114/323 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TRPA1 | c.1823G>T p.C608F | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- TRPM1 | c.3376G>T p.G1126C | Missense Mutation (SNP) | VAF 145/553 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM5 | c.2506A>T p.T836S | Missense Mutation (SNP) | VAF 81/286 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- TRPM6 | c.4783C>A p.P1595T | Missense Mutation (SNP) | VAF 159/525 reads (30%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TSHZ2 | c.2478G>T p.R826S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSNARE1 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.238); called by muse, mutect2
- TTLL11 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.55223G>T p.R18408L (on ENST00000591111; = p.R10984L on NM_003319.4) | Missense Mutation (SNP) | VAF 191/762 reads (25%) | PolyPhen probably damaging (0.998); called by muse, varscan2
- TTN | c.25926G>T p.W8642C (on ENST00000591111; = p.W7715C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/335 reads (25%) | PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TTN | c.22712C>A p.P7571Q (on ENST00000591111; = p.P6644Q on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUB | c.93G>T p.R31= (on ENST00000299506 / NM_177972.3; = p.R86= on NM_003320.4) | Splice Region (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- TXNDC16 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TXNRD1 | c.1473G>T p.E491D (on ENST00000525566 / NM_001093771.3; = p.E393D on NM_003330.4) | Missense Mutation (SNP) | VAF 150/391 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- TXNRD3 | c.28G>T p.G10W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TYR | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TYW1B | c.1956G>T p.K652N | Missense Mutation (SNP) | VAF 49/453 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- UBAP2 | c.1906G>T p.E636* | Nonsense Mutation (SNP) | VAF 105/287 reads (37%) | called by muse, mutect2, varscan2
- UMAD1 | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNC13B | c.3024G>A p.W1008* | Nonsense Mutation (SNP) | VAF 90/268 reads (34%) | called by muse, mutect2, varscan2
- UNC79 | c.2372G>T p.C791F (on ENST00000393151 / NM_001346218.2; = p.C614F on NM_020818.5) | Missense Mutation (SNP) | VAF 120/463 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- USP9X | c.5747_5752del p.M1916_K1917del | In Frame Del (DEL) | VAF 104/254 reads (41%) | called by mutect2, pindel, varscan2
- VANGL1 | c.628del p.D210Tfs*61 | Frame Shift Del (DEL) | VAF 192/755 reads (25%) | called by mutect2, pindel, varscan2
- VCAN | c.4383G>T p.L1461F | Missense Mutation (SNP) | VAF 316/796 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- VIL1 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- VWA5B2 | c.2809A>T p.T937S | Missense Mutation (SNP) | VAF 72/320 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZAN | c.6896T>C p.I2299T | Missense Mutation (SNP) | VAF 96/365 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ZC3H12C | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 195/736 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 65/227 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- ZFP57 | c.309G>T p.Q103H | Missense Mutation (SNP) | VAF 194/704 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- ZIK1 | c.325C>A p.L109M | Missense Mutation (SNP) | VAF 101/326 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- ZNF106 | c.2332C>A p.L778I | Missense Mutation (SNP) | VAF 66/429 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ZNF132 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF223 | c.920G>T p.C307F | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ZNF277 | c.1009G>C p.G337R | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF492 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ZNF536 | c.3137G>T p.R1046L | Missense Mutation (SNP) | VAF 100/247 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF550 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 54/160 reads (34%) | called by muse, mutect2, varscan2
- ZNF579 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- ZNF652 | c.1430G>T p.R477L | Missense Mutation (SNP) | VAF 159/624 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF667 | c.549G>T p.Q183H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ZNF766 | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF780A | c.1916A>C p.K639T | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- ZNF80 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF804B | c.3991C>A p.Q1331K | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, varscan2
- ZSCAN10 | c.2129C>A p.S710Y (on ENST00000252463; = p.S765Y on NM_032805.3) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN12 | c.437dup p.L146Ffs*27 | Frame Shift Ins (INS) | VAF 45/302 reads (15%) | called by mutect2, pindel, varscan2
- ZSWIM2 | c.786del p.F262Lfs*24 | Frame Shift Del (DEL) | VAF 85/459 reads (19%) | called by mutect2, pindel, varscan2
- AC244197.3 | c.609A>C p.A203= | Silent (SNP) | VAF 124/186 reads (67%) | called by muse, mutect2, varscan2
- ACRV1 | c.510A>T p.S170= | Silent (SNP) | VAF 81/277 reads (29%) | called by muse, mutect2, varscan2
- ADAM11 | c.1326G>C p.L442= | Silent (SNP) | VAF 72/228 reads (32%) | called by muse, mutect2, varscan2
- ADAM12 | c.144G>T p.G48= | Silent (SNP) | VAF 60/299 reads (20%) | catalogued as rs763959440; called by muse, mutect2, varscan2
- ADAMTSL3 | c.300G>T p.R100= | Silent (SNP) | VAF 20/204 reads (10%) | called by muse, mutect2
- ADRA2A | c.462C>A p.I154= | Silent (SNP) | VAF 30/227 reads (13%) | catalogued as COSV54527846; called by muse, mutect2, varscan2
- ALDOB | c.1080C>T p.A360= | Silent (SNP) | VAF 303/1134 reads (27%) | called by muse, mutect2, varscan2
- AMDHD1 | c.534G>T p.R178= | Silent (SNP) | VAF 164/357 reads (46%) | called by muse, mutect2, varscan2
- ANK3 | c.4524A>G p.T1508= | Silent (SNP) | VAF 100/427 reads (23%) | called by muse, mutect2, varscan2
- ANO4 | c.1104A>G p.G368= (on ENST00000392977 / NM_001286615.2; = p.G333= on NM_178826.4) | Silent (SNP) | VAF 76/475 reads (16%) | called by muse, mutect2, varscan2
- AOAH | c.165T>A p.A55= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- AP3B2 | c.2469C>A p.P823= (on ENST00000261722; = p.P817= on NM_004644.5) | Silent (SNP) | VAF 99/650 reads (15%) | called by muse, mutect2, varscan2
- ATP7B | c.3123G>T p.R1041= | Silent (SNP) | VAF 79/309 reads (26%) | called by muse, mutect2, varscan2
- B3GAT2 | c.639T>C p.G213= | Silent (SNP) | VAF 31/111 reads (28%) | called by muse, mutect2, varscan2
- BAALC | c.495C>A p.I165= (on ENST00000297574 / NM_001364874.1; = p.I130= on NM_024812.3) | Silent (SNP) | VAF 81/333 reads (24%) | called by muse, mutect2, varscan2
- BASP1 | c.645G>T p.P215= | Silent (SNP) | VAF 36/131 reads (27%) | catalogued as COSV59473076; called by muse, mutect2, varscan2
- BDKRB1 | c.54C>A p.L18= | Silent (SNP) | VAF 74/302 reads (25%) | catalogued as COSV53706242; called by muse, mutect2, varscan2
- BLK | c.732C>A p.V244= | Silent (SNP) | VAF 64/625 reads (10%) | called by muse, mutect2, varscan2
- BPIFB4 | c.1116C>A p.T372= | Silent (SNP) | VAF 65/359 reads (18%) | catalogued as rs575666496; called by muse, mutect2, varscan2
- BST1 | c.48G>T p.L16= | Silent (SNP) | VAF 117/390 reads (30%) | called by muse, mutect2, varscan2
- C1QTNF9B | c.102C>A p.P34= | Silent (SNP) | VAF 37/223 reads (17%) | called by muse, mutect2, varscan2
- CACNA1H | c.693G>A p.G231= | Silent (SNP) | VAF 62/272 reads (23%) | catalogued as rs781458681; called by muse, mutect2, varscan2
- CACNA2D3 | c.1518G>T p.V506= | Silent (SNP) | VAF 100/401 reads (25%) | called by muse, mutect2, varscan2
- CADM2 | c.543A>T p.T181= (on ENST00000407528 / NM_001167674.2; = p.T183= on NM_153184.4) | Silent (SNP) | VAF 131/421 reads (31%) | called by muse, mutect2, varscan2
- CARD11 | c.2373C>T p.C791= | Silent (SNP) | VAF 60/450 reads (13%) | catalogued as COSV62756787; called by muse, mutect2, varscan2
- CARD9 | c.1131G>A p.E377= | Silent (SNP) | VAF 61/158 reads (39%) | called by muse, mutect2, varscan2
- CASKIN1 | c.1218C>T p.H406= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as rs751511290; called by muse, mutect2, varscan2
303 further variants in this file (0 protein-altering or splice-affecting, 190 silent, 113 other) are not listed here.
